Somatic mutation profile of tumor specimen C3N-01765-01 (aliquot CPT0116940006) from CPTAC case C3N-01765, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.3 years (21,285 days).
Specimen C3N-01765-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1436e071-9c4d-4006-b119-2ecfa1664339.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01765-31 (Blood Derived Normal), aliquot CPT0117000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a89363a-dc18-4ee9-9686-40b6c7d157d2

The open-access MAF lists 990 somatic variants for this specimen: 646 protein-altering or splice-affecting, 221 silent, 123 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 490, Silent 221, Frame Shift Ins 90, Intron 67, Frame Shift Del 24, Nonsense Mutation 19, 3'UTR 18, RNA 17, Splice Site 16, 5'UTR 10, 5'Flank 6, 3'Flank 5.

Variants (750 of 990; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 40/161 reads (25%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 24/143 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.5950C>T p.R1984* | Nonsense Mutation (SNP) | VAF 16/294 reads (5%) | catalogued as rs1554826746, COSV53039810; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHOX | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs886043634, CM056986, CM070262, CM074516; ClinVar: pathogenic; called by muse, mutect2
- AAMP | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs896226626; called by muse, mutect2
- ABCA4 | c.4510G>A p.E1504K | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs190370456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC1 | c.3413G>A p.R1138Q | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1387333493; called by muse, mutect2
- ABHD16B | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs368544774; called by muse, mutect2, varscan2
- ACOT7 | c.1126G>A p.A376T (on ENST00000377855 / NM_181864.3; = p.A366T on NM_007274.4) | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs192112480; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3497dup p.N1166Kfs*26 | Frame Shift Ins (INS) | VAF 21/91 reads (23%) | catalogued as rs1567281568; called by mutect2, pindel, varscan2
- ADGRA2 | c.3745A>G p.M1249V | Missense Mutation (SNP) | VAF 93/356 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1471188065; called by muse, mutect2, varscan2
- ADGRV1 | c.1563dup p.P522Sfs*8 | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs763243011; called by mutect2, pindel, varscan2
- ADORA3 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as rs764124230, COSV53986994; called by muse, mutect2, varscan2
- ADSL | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 123/560 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760189192, COSV99341883; called by muse, mutect2, varscan2
- AK1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1443602211; called by muse, mutect2
- AKAP8L | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 38/157 reads (24%) | catalogued as rs753551404; called by muse, mutect2, varscan2
- AKT2 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs758767505, COSV60908520; called by muse, mutect2, varscan2
- ALDH3A1 | c.614C>G p.T205S | Missense Mutation (SNP) | VAF 122/458 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56736899; called by muse, mutect2, varscan2
- ALOX15 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs149366613; called by muse, mutect2, varscan2
- AMPD3 | c.1051C>T p.R351W (on ENST00000396553 / NM_001025389.2; = p.R360W on NM_000480.3) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs780915004, COSV67330088; called by muse, mutect2
- ANXA4 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268760; called by muse, mutect2
- AP2M1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53050298; called by muse, mutect2, varscan2
- APTX | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1269363354; called by muse, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | catalogued as rs774148781; called by mutect2, varscan2
- ARFIP1 | c.812G>A p.R271H (on ENST00000353617 / NM_001287432.1; = p.R239H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972103124, COSV61883329; called by muse, mutect2, varscan2
- ARHGAP23 | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs778586642; called by muse, mutect2, varscan2
- ARHGAP35 | c.4295G>A p.C1432Y | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.334); catalogued as COSV68328975; called by muse, mutect2
- ARID1A | c.6707G>C p.R2236P | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV61379307; called by muse, mutect2, varscan2
- ARRDC5 | c.175G>A p.V59M (on ENST00000381781; = p.V45M on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/596 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs544143370; called by muse, mutect2, varscan2
- ATAD2B | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53198340; called by muse, mutect2, varscan2
- ATP6AP1 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 125/506 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs782737307, COSV63895538; called by muse, mutect2, varscan2
- ATXN1L | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1313192823; called by muse, mutect2
- B3GNT6 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1555027583; called by muse, mutect2
- BAIAP3 | c.1814A>G p.Y605C | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs771628072; called by muse, mutect2, varscan2
- BCAT2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 87/402 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs1370313449, COSV100302541; called by muse, mutect2, varscan2
- BCOR | c.3754A>G p.I1252V (on ENST00000378444 / NM_001123385.2; = p.I1218V on NM_017745.6) | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV60715405; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 44/252 reads (17%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- BMP2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 50/388 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs752683518, COSV66577006, COSV66578595; called by muse, mutect2, varscan2
- C1QA | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1215721677; called by muse, mutect2
- C2orf42 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1354519947; called by muse, mutect2, varscan2
- CACNA1E | c.2562del p.S855Pfs*52 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | catalogued as rs753503928; called by mutect2, pindel, varscan2
- CACNG1 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 65/557 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs146687061; called by muse, mutect2, varscan2
- CASKIN2 | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs370216413, COSV100050703; called by muse, mutect2
- CATSPERD | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193586683, COSV101062424, COSV67536988; called by muse, mutect2, varscan2
- CAVIN1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 142/472 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.054); catalogued as COSV63811426; called by muse, mutect2, varscan2
- CCDC62 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs781307131, COSV53435490; called by muse, mutect2, varscan2
- CCNY | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV55184250; called by muse, varscan2
- CDH23 | c.134A>T p.D45V | Missense Mutation (SNP) | VAF 82/267 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99822881; called by muse, mutect2, varscan2
- CDRT15L2 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.302); catalogued as rs1211714383; called by muse, mutect2, varscan2
- CEP85 | c.1579T>G p.C527G | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as rs1277767188; called by muse, mutect2, varscan2
- CIT | c.5498-1G>A p.X1833_splice | Splice Site (SNP) | VAF 9/146 reads (6%) | catalogued as COSV55864858; called by muse, mutect2
- CLDN12 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs865961955; called by muse, mutect2
- CLDN16 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758946923, CM034403, CP015768, COSV53229765; called by muse, mutect2, varscan2
- CLIP2 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs782683129, COSV99791187; called by muse, mutect2
- CNGA2 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | catalogued as rs1318609100, COSV61703233; called by muse, mutect2, varscan2
- COL11A2 | c.2669C>T p.P890L (on ENST00000341947 / NM_080680.3; = p.P783L on NM_080679.2) | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs764307090; called by muse, mutect2
- COL2A1 | c.509dup p.G171Wfs*18 | Frame Shift Ins (INS) | VAF 48/227 reads (21%) | catalogued as COSV61530596; called by mutect2, pindel, varscan2
- COL4A4 | c.4546G>A p.V1516I | Missense Mutation (SNP) | VAF 36/275 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs199517662; called by muse, mutect2, varscan2
- COMP | c.80-7G>A | Splice Region (SNP) | VAF 44/394 reads (11%) | catalogued as rs758487737; called by muse, mutect2, varscan2
- CRY1 | c.1218del p.Q407Nfs*30 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as rs35271440; called by mutect2, pindel, varscan2
- CRYGN | c.547T>C p.*183Rext*35 | Nonstop Mutation (SNP) | VAF 12/224 reads (5%) | catalogued as COSV61563888; called by muse, mutect2
- CSMD3 | c.5461C>T p.P1821S (on ENST00000297405 / NM_001363185.1; = p.P1717S on NM_052900.3) | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99846867; called by muse, mutect2, varscan2
- CTTN | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367827428, COSV57235745; called by muse, mutect2, varscan2
- CYC1 | c.276dup p.S93Qfs*26 | Frame Shift Ins (INS) | VAF 39/172 reads (23%) | catalogued as rs756254049; called by mutect2, varscan2
- CYFIP2 | c.877A>C p.S293R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV59040962; called by muse, mutect2, varscan2
- DCAF1 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60044999; called by muse, mutect2, varscan2
- DCC | c.70A>G p.S24G | Missense Mutation (SNP) | VAF 148/634 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV71425330; called by muse, mutect2, varscan2
- DDX60L | c.2402T>C p.V801A | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99488586; called by muse, mutect2, varscan2
- DGKQ | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs909743257; called by muse, mutect2
- DNAH1 | c.10489C>T p.R3497C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1011281568; ClinVar: uncertain significance; called by muse, mutect2
- DNAJA3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753693250, COSV99276332; called by muse, mutect2, varscan2
- DOCK11 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1243801731; called by muse, mutect2
- DPP9 | c.155C>T p.A52V (on ENST00000598800; = p.A81V on NM_139159.5) | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.055); catalogued as rs374165392; called by muse, mutect2
- DYRK4 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs749869548; called by muse, mutect2, varscan2
- EGFLAM | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as COSV59316038; called by muse, mutect2, varscan2
- EIF4B | c.1806T>A p.D602E | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.978); catalogued as COSV50408395; called by muse, mutect2, varscan2
- ELAVL1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 10/249 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.079); catalogued as COSV60965804; called by muse, mutect2
- EPHB4 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs767324545; called by mutect2, varscan2
- EPS8L1 | c.1351C>T p.R451W (on ENST00000201647 / NM_133180.3; = p.R324W on NM_017729.3) | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as COSV52382795; called by muse, mutect2
- ERG | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 51/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195312059, COSV55735323; called by muse, mutect2, varscan2
- ERVFRD-1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs774469576; called by muse, mutect2, varscan2
- FAM126B | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99628300; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 76/354 reads (21%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM214B | c.1002dup p.S335Qfs*19 | Frame Shift Ins (INS) | VAF 57/232 reads (25%) | catalogued as rs775865641; called by mutect2, varscan2
- FAN1 | c.34del p.R12Gfs*45 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs752820596; called by mutect2, pindel, varscan2
- FAT2 | c.10383del p.Y3462Tfs*16 | Frame Shift Del (DEL) | VAF 92/462 reads (20%) | catalogued as rs747011618; called by mutect2, pindel, varscan2
- FGD2 | c.1912C>T p.R638W | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs144179620; called by muse, mutect2, varscan2
- FH | c.1316A>C p.Q439P | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1553340690, CM060265; called by muse, varscan2
- FKBP14 | c.85dup p.I29Nfs*2 | Frame Shift Ins (INS) | VAF 19/94 reads (20%) | catalogued as rs1470738681; called by mutect2, pindel, varscan2
- FOXD2 | c.641G>A p.G214D | Missense Mutation (SNP) | VAF 21/748 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58304621; called by muse, mutect2
- FOXK1 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.366); catalogued as COSV100195512; called by muse, mutect2, varscan2
- FUT6 | c.225A>G p.I75M | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1291763177; called by muse, mutect2
- FUT6 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 96/340 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1382361313; called by muse, mutect2
- GARNL3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270744732, COSV100150089; called by muse, mutect2, varscan2
- GFM1 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs780301536; called by muse, mutect2, varscan2
- GFRA2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 101/475 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs754540853, COSV60778478; called by muse, mutect2, varscan2
- GINS4 | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1176850648; called by muse, mutect2, varscan2
- GLS2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs925971587; called by muse, mutect2, varscan2
- GNAZ | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1379507136, COSV50737848; called by muse, mutect2, varscan2
- GPATCH8 | c.4430C>T p.T1477I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV59196383; called by muse, mutect2
- GPR161 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773910892, COSV54791191; called by muse, mutect2, varscan2
- GRIA1 | c.1640A>T p.Y547F | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV53597482; called by muse, mutect2, varscan2
- GRIA2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs752525141, COSV52391015, COSV52399091; called by muse, mutect2, varscan2
- GRIN2C | c.2452G>A p.V818I | Missense Mutation (SNP) | VAF 32/539 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140182608, COSV99500902; called by muse, mutect2
- GRIP1 | c.2137G>A p.A713T (on ENST00000359742 / NM_001379345.1; = p.A661T on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV54025054; called by muse, mutect2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 12/33 reads (36%) | catalogued as rs754199513; called by mutect2, varscan2
- H3C2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 88/358 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as rs866029344; called by muse, mutect2, varscan2
- HOXC12 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1382781198; called by muse, mutect2
- HTR1A | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as rs1467451068, COSV100109350; called by muse, mutect2
- IFT122 | c.3604G>A p.A1202T (on ENST00000348417 / NM_052989.3; = p.A1143T on NM_018262.4) | Missense Mutation (SNP) | VAF 21/444 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56202698, COSV99959405; called by muse, mutect2
- IFT172 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs202089120; called by muse, mutect2
- IGSF8 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs753924525; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1394614053, COSV61176798; called by muse, mutect2
- IL2RG | c.1082del p.P361Hfs*5 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs745545309; called by pindel, varscan2
- IMP4 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as rs371172186; called by muse, mutect2
- INPPL1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773085707, COSV53357373; called by muse, mutect2, varscan2
- INTU | c.1772dup p.L591Ffs*54 | Frame Shift Ins (INS) | VAF 37/200 reads (19%) | catalogued as rs1442016097; called by mutect2, pindel, varscan2
- IQSEC2 | c.1826G>A p.R609H (on ENST00000642864 / NM_001111125.3; = p.R404H on NM_015075.2) | Missense Mutation (SNP) | VAF 46/193 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as rs1556863238, COSV64726942; called by muse, mutect2, varscan2
- ITGA10 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs202222786; called by muse, mutect2, varscan2
- ITLN2 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs777412143; called by muse, mutect2
- ITPKC | c.756dup p.Q253Tfs*4 | Frame Shift Ins (INS) | VAF 72/292 reads (25%) | catalogued as rs1484889842; called by mutect2, pindel, varscan2
- JAG2 | c.3473C>T p.P1158L | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs376149193; called by muse, mutect2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 38/70 reads (54%) | catalogued as rs755650243; called by mutect2, varscan2
- JAM3 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 26/483 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs893550867; called by muse, mutect2
- KANSL3 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62616286, COSV62625680; called by muse, mutect2, varscan2
- KCNA1 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.35); catalogued as rs139383685, COSV66836871; called by muse, mutect2
- KCNA4 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 39/133 reads (29%) | catalogued as COSV60252161; called by muse, mutect2, varscan2
- KCNB1 | c.2206dup p.R736Pfs*4 | Frame Shift Ins (INS) | VAF 43/214 reads (20%) | catalogued as rs759902465; called by mutect2, varscan2
- KCNJ15 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1383475103; called by muse, mutect2
- KCTD11 | c.271G>A p.G91R (on ENST00000333751 / NM_001363642.1; = p.G52R on NM_001002914.2) | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1260908116, COSV50137631; called by muse, mutect2, varscan2
- KHSRP | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101231246; called by muse, mutect2, varscan2
- KIAA0895L | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs955997882, COSV51783678; called by muse, mutect2, varscan2
- KIAA1328 | c.1046dup p.G350Wfs*7 | Frame Shift Ins (INS) | VAF 22/97 reads (23%) | catalogued as rs764395931; called by mutect2, varscan2
- KIF20A | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs373613515; called by muse, mutect2, varscan2
- KIF7 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 105/479 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.089); catalogued as COSV67999502; called by muse, mutect2, varscan2
- KLF9 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as rs750014758, COSV65807485; called by muse, mutect2
- KLHL36 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.417); catalogued as rs1178678605; called by muse, mutect2
- KMT2D | c.7548dup p.N2517Qfs*138 | Frame Shift Ins (INS) | VAF 23/83 reads (28%) | catalogued as rs750341925; called by mutect2, pindel, varscan2
- KRTAP19-8 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV101239218; called by muse, mutect2
- KRTAP25-1 | c.29dup p.S11Qfs*2 | Frame Shift Ins (INS) | VAF 13/48 reads (27%) | catalogued as rs919385570; called by mutect2, varscan2
- LAMA2 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 24/462 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.05); catalogued as rs367622987; ClinVar: uncertain significance; called by muse, mutect2
- LCOR | c.4341dup p.K1448Qfs*9 | Frame Shift Ins (INS) | VAF 36/162 reads (22%) | catalogued as rs1432549182; called by mutect2, pindel, varscan2
- LHX1 | c.1194dup p.E399Rfs*65 | Frame Shift Ins (INS) | VAF 68/172 reads (40%) | catalogued as rs775423572; called by mutect2, varscan2
- LONP1 | c.2290G>A p.V764M | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369452747; called by muse, mutect2, varscan2
- LRP2 | c.11293C>T p.R3765* | Nonsense Mutation (SNP) | VAF 78/290 reads (27%) | catalogued as COSV55548258; called by muse, mutect2, varscan2
- LRRC25 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 117/464 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100170613; called by muse, mutect2, varscan2
- LTBP1 | c.4439G>A p.G1480D (on ENST00000404816 / NM_206943.4; = p.G1154D on NM_000627.4) | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468614768; called by muse, mutect2, varscan2
- LUC7L2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54925184; called by muse, mutect2, varscan2
- LYST | c.10192C>T p.R3398* | Nonsense Mutation (SNP) | VAF 10/230 reads (4%) | catalogued as rs1451596846, COSV67703719; called by muse, mutect2
- LZIC | c.570dup p.*191Mfs*8 | Frame Shift Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs753028254; called by mutect2, varscan2
- LZTR1 | c.2480A>C p.H827P | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.522); catalogued as rs1301431226; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 41/202 reads (20%) | catalogued as rs752869239; called by mutect2, varscan2
- MAN2A2 | c.2954G>A p.R985H | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs771860667, COSV64638121; called by muse, mutect2, varscan2
- MARK2 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs1265697640; called by muse, mutect2, varscan2
- MBNL2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 71/572 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.201); catalogued as rs752231087; called by muse, mutect2, varscan2
- MEGF8 | c.497dup p.P167Sfs*2 | Frame Shift Ins (INS) | VAF 32/116 reads (28%) | catalogued as rs762115034; called by mutect2, varscan2
- MEX3A | c.1334dup p.E447Rfs*8 | Frame Shift Ins (INS) | VAF 30/122 reads (25%) | catalogued as rs781091579; called by mutect2, pindel
- MICAL1 | c.1487A>G p.D496G | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs1341623743; called by muse, mutect2, varscan2
- MIF4GD | c.430A>G p.K144E (on ENST00000325102 / NM_001370592.1; = p.K178E on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs751475077; called by muse, mutect2, varscan2
- MLST8 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs774324416; called by muse, mutect2
- MLYCD | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 48/485 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as rs200573073, COSV52305658; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 10/101 reads (10%) | catalogued as rs757691558; called by mutect2, pindel
- MYB | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs777923027, COSV57196169, COSV57200862; called by muse, mutect2, varscan2
- MYBBP1A | c.1982A>G p.Q661R | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as rs745888268; called by muse, mutect2, varscan2
- MYH4 | c.5258G>A p.R1753H | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs187295127, COSV55113639; called by muse, mutect2, varscan2
- MYO15B | c.4589C>T p.T1530M | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as rs774317035; called by muse, mutect2, varscan2
- MYO18A | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 52/218 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs765074551; called by muse, mutect2, varscan2
- MYOC | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50673786; called by muse, mutect2, varscan2
- NDST2 | c.2068dup p.A690Gfs*18 | Frame Shift Ins (INS) | VAF 61/311 reads (20%) | catalogued as rs1565096048; called by mutect2, pindel, varscan2
- NDUFB11 | c.404C>T p.P135L (on ENST00000377811 / NM_001135998.3; = p.P145L on NM_019056.6) | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1293922210; called by muse, varscan2
- NID2 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs774075467, COSV53493966; called by muse, mutect2, varscan2
- NIPA2 | c.98dup p.L35Pfs*21 | Frame Shift Ins (INS) | VAF 26/112 reads (23%) | catalogued as rs145147241; called by mutect2, varscan2
- NLRP12 | c.2735C>T p.T912M | Missense Mutation (SNP) | VAF 55/504 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs750086255, COSV100144938; called by muse, mutect2, varscan2
- NPAS4 | c.2123C>T p.T708M | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759012677, COSV60651798; called by muse, mutect2, varscan2
- NSG1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs765800071; called by muse, mutect2, varscan2
- NUMA1 | c.5405G>A p.R1802H | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.78); catalogued as rs146335857, COSV52621970; called by muse, mutect2, varscan2
- NWD2 | c.3742G>A p.A1248T | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1355461770, COSV58756243; called by muse, mutect2, varscan2
- OBSCN | c.9775G>A p.G3259R | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs778061332; called by muse, mutect2
- ONECUT1 | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100009064; called by muse, mutect2, varscan2
- OR4A5 | c.849A>G p.I283M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV99081992; called by muse, mutect2
- OSBPL2 | c.543dup p.I182Hfs*12 (on ENST00000313733 / NM_144498.4; = p.I170Hfs*12 on NM_014835.4) | Frame Shift Ins (INS) | VAF 20/115 reads (17%) | catalogued as rs780916980; called by mutect2, varscan2
- OSBPL9 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs140080386, COSV61866909; called by muse, mutect2, varscan2
- PARD6G | c.940dup p.Q314Pfs*73 | Frame Shift Ins (INS) | VAF 34/188 reads (18%) | catalogued as rs755217812; called by mutect2, varscan2
- PCDHA10 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as rs782483771, COSV100251533; called by muse, mutect2, varscan2
- PCDHA11 | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56536351; called by muse, mutect2
- PCDHA5 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 26/626 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV65353977; called by muse, mutect2
- PCDHB10 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.215); catalogued as rs782338014; called by muse, mutect2, varscan2
- PCDHB5 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50677652; called by muse, mutect2, varscan2
- PCDHGA12 | c.1886C>G p.A629G | Missense Mutation (SNP) | VAF 122/522 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV52761643; called by muse, mutect2, varscan2
- PCDHGA2 | c.1981A>G p.T661A | Missense Mutation (SNP) | VAF 153/648 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV54035952; called by muse, mutect2, varscan2
- PCNX3 | c.3124C>T p.R1042C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs761452257, COSV63136937; called by muse, mutect2, varscan2
- PCNX3 | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1463349670, COSV63134548; called by muse, mutect2, varscan2
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 26/96 reads (27%) | catalogued as rs746601412; called by mutect2, varscan2
- PEX5 | c.1823G>A p.R608H (on ENST00000420616; = p.R600H on NM_000319.5) | Missense Mutation (SNP) | VAF 85/634 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs201158549; called by muse, mutect2, varscan2
- PFKM | c.717G>A p.W239* | Nonsense Mutation (SNP) | VAF 81/603 reads (13%) | catalogued as rs1348734621; called by muse, mutect2, varscan2
- PGM1 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1476203008, COSV64301694; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | catalogued as rs769717544; called by mutect2, varscan2
- PIBF1 | c.33dup p.V12Sfs*5 | Frame Shift Ins (INS) | VAF 8/42 reads (19%) | catalogued as rs925772654; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | catalogued as rs749506841; called by mutect2, varscan2
- PKHD1 | c.10200G>A p.M3400I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1223533683, COSV64390072; called by muse, mutect2
- PLEKHH3 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1348791164; called by muse, mutect2, varscan2
- PLG | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as rs139357983; called by muse, mutect2, varscan2
- PNLDC1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs745935275, COSV51706726, COSV51706896; called by muse, mutect2, varscan2
- POLG | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99174443; called by muse, mutect2, varscan2
- POLR2A | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59490305; called by muse, mutect2
- POR | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374406028; called by muse, mutect2
- PPARGC1B | c.2395A>G p.S799G | Missense Mutation (SNP) | VAF 94/328 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs762471952; called by muse, varscan2
- PPIP5K2 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs370259216, COSV100384038; called by muse, mutect2
- PPP1R13B | c.3071C>T p.A1024V | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768657019, COSV52455986; called by muse, mutect2
- PPP1R15A | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs371798766, COSV52339333; called by muse, mutect2, varscan2
- PPP1R26 | c.2532T>G p.F844L | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63357494; called by muse, mutect2, varscan2
- PPP6R2 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53293687; called by muse, mutect2, varscan2
- PRDM15 | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs149309111; called by muse, mutect2
- PRELID3A | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs562376554; called by muse, mutect2
- PRKCE | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs144454815, COSV100079548; called by muse, mutect2, varscan2
- PRPF8 | c.5539G>A p.A1847T | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59263729; called by muse, mutect2, varscan2
- PRSS35 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as rs765422823; called by muse, mutect2, varscan2
- PTEN | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV64290065, COSV64301645; called by muse, mutect2, varscan2
- PTEN | c.828T>A p.N276K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64299696, COSV64304659; called by muse, varscan2
- PTPN23 | c.3560A>G p.D1187G | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55542794; called by muse, mutect2, varscan2
- PTPRN2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 65/274 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1047290785, COSV67026880; called by muse, mutect2, varscan2
- PTPRT | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62005935; called by muse, mutect2, varscan2
- RAB40B | c.801dup p.K268Qfs*96 | Frame Shift Ins (INS) | VAF 52/236 reads (22%) | catalogued as rs764520009; called by mutect2, varscan2
- RAP1GAP | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs1218707048; called by muse, mutect2, varscan2
- REC8 | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as rs1438221271, COSV61018879; called by muse, mutect2
- RERE | c.3249dup p.S1084Vfs*19 | Frame Shift Ins (INS) | VAF 26/148 reads (18%) | catalogued as rs745806637; ClinVar: uncertain significance; called by mutect2, varscan2
- RGS12 | c.3870dup p.G1291Rfs*45 | Frame Shift Ins (INS) | VAF 12/42 reads (29%) | catalogued as rs751982308; called by mutect2, varscan2
- RHBDF2 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs754696049, COSV57421664; called by muse, mutect2, varscan2
- RNF114 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776148672; called by muse, mutect2, varscan2
- RNF148 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 19/122 reads (16%) | catalogued as rs773636874; called by muse, mutect2, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1436309196; called by mutect2, pindel
- ROBO1 | c.4457C>T p.P1486L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); catalogued as rs759693235; called by muse, mutect2, varscan2
- RPH3A | c.1718G>A p.R573H (on ENST00000389385 / NM_001143854.2; = p.R569H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1479500368, COSV66990126; called by muse, mutect2, varscan2
- RREB1 | c.4595G>A p.R1532H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100619160; called by muse, mutect2, varscan2
- RSPRY1 | c.1117A>G p.M373V | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV68027594; called by muse, mutect2, varscan2
- RYR2 | c.14151+8T>C | Splice Region (SNP) | VAF 8/20 reads (40%) | catalogued as rs1015721132; called by mutect2, varscan2
- SAFB | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 155/641 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1323492285; called by muse, mutect2, varscan2
- SCAF1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.927); catalogued as rs1225415263, COSV62183877; called by mutect2, varscan2
- SECISBP2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.353); catalogued as rs767788315; called by muse, mutect2, varscan2
- SEMA5A | c.2021A>G p.Q674R | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.533); catalogued as COSV101228622; called by muse, mutect2, varscan2
- SFXN2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as rs752709134, COSV64011937; called by muse, mutect2, varscan2
- SGSH | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as rs532180050; called by muse, mutect2, varscan2
- SH2B3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs761530554, COSV57983885; called by muse, mutect2, varscan2
- SLC18A1 | c.1381A>G p.M461V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs573496522; called by muse, mutect2, varscan2
- SLC27A1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886598213, COSV53100742; called by muse, mutect2
- SLC29A4 | c.1487C>T p.T496M | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); catalogued as COSV51877299; called by muse, mutect2
- SLC36A2 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 64/505 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs374963069; called by muse, mutect2, varscan2
- SLC6A4 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV55569312; called by muse, mutect2
- SLIT1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.272); catalogued as rs767760876; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SPATS2L | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1342966326; called by muse, mutect2
- SPR | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1486552702; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 12/280 reads (4%) | PolyPhen probably damaging (0.998); catalogued as rs1294543745, COSV100231430; called by muse, mutect2
- STARD13 | c.2492G>A p.R831Q (on ENST00000336934 / NM_001243476.3; = p.R713Q on NM_052851.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs768401147, COSV55232351; called by muse, mutect2, varscan2
- STARD9 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.097); catalogued as rs576562056; called by muse, mutect2, varscan2
- STX3 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376160845; called by muse, mutect2
- SVIL | c.5586dup p.M1863Dfs*18 (on ENST00000355867 / NM_021738.3; = p.M1437Dfs*18 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs770033147; called by mutect2, varscan2
- SVOPL | c.1028A>G p.D343G (on ENST00000419765; = p.D191G on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as rs750533712, COSV55992047; called by muse, mutect2, varscan2
- SYT7 | c.46G>T p.D16Y | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV99801793; called by muse, mutect2, varscan2
- TAAR5 | c.53A>C p.Y18S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57799678; called by muse, mutect2, varscan2
- TAF5L | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51086404; called by muse, mutect2
- TAMM41 | c.806dup p.N269Kfs*14 | Frame Shift Ins (INS) | VAF 56/258 reads (22%) | catalogued as rs768826552; called by mutect2, pindel, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 38/238 reads (16%) | catalogued as COSV61906772; called by mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 16/142 reads (11%) | catalogued as rs763321097; called by mutect2, varscan2
- TEAD2 | c.607dup p.Q203Pfs*42 | Frame Shift Ins (INS) | VAF 12/66 reads (18%) | catalogued as rs752700410; called by mutect2, varscan2
- TGFBR1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66625946; called by muse, mutect2
- TIMD4 | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50854547, COSV50858835; called by muse, mutect2, varscan2
- TJP2 | c.2880+8G>A | Splice Region (SNP) | VAF 17/110 reads (15%) | catalogued as rs756700057; called by muse, mutect2, varscan2
- TLX2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as rs568571616, COSV52046036; called by muse, mutect2, varscan2
- TMEM19 | c.691A>T p.T231S | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99876902; called by muse, mutect2, varscan2
- TNFAIP3 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); catalogued as rs1405321250, COSV52797285, COSV52798105; called by muse, mutect2, varscan2
- TPPP | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs770643131, COSV62193193; called by muse, varscan2
- TRANK1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1423613020; called by muse, mutect2, varscan2
- TRIM26 | c.845del p.K282Rfs*16 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | catalogued as rs1271434984; called by mutect2, varscan2
- TRIM3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs775829317; called by muse, mutect2, varscan2
- TRIM7 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1423217925; called by muse, mutect2
- TRIM74 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 22/535 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs1554506359, COSV53533563; called by muse, mutect2
- TSSK3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs374749640; called by muse, mutect2, varscan2
- TUFM | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.172); catalogued as rs1167098942; called by muse, mutect2
- TYR | c.1133A>G p.Q378R | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs1178625714; called by muse, mutect2, varscan2
- U2AF2 | c.330G>A p.M110I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV99069159; called by muse, mutect2, varscan2
- UVRAG | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs778234179, COSV62101630; called by muse, mutect2, varscan2
- VPS13B | c.9621A>C p.R3207S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100663407; called by muse, mutect2, varscan2
- VTI1A | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs773314032, COSV67579183; called by muse, mutect2, varscan2
- WDR4 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs372799050; called by muse, mutect2, varscan2
- WIPF1 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV55810997; called by muse, mutect2
- XIAP | c.1190T>A p.I397N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63023769; called by muse, mutect2, varscan2
- ZBTB16 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as rs1206143172; called by muse, mutect2
- ZC3H15 | c.100A>G p.K34E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV61923706; called by muse, mutect2, varscan2
- ZC3H3 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 50/298 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs554646607, COSV52788503; called by muse, mutect2, varscan2
- ZFAT | c.1453C>A p.Q485K | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV64737482; called by muse, mutect2, varscan2
- ZFX | c.1040T>C p.M347T | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs1569169439; called by muse, mutect2, varscan2
- ZNF426 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs760169066; called by muse, mutect2, varscan2
- ZNF469 | c.10896dup p.P3633Afs*138 (on ENST00000437464; = p.P3661Afs*138 on NM_001367624.2) | Frame Shift Ins (INS) | VAF 50/220 reads (23%) | catalogued as rs1157911510; called by mutect2, varscan2
- ZNF550 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs144170900; called by muse, mutect2, varscan2
- ZNF717 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); catalogued as rs535644960; called by muse, varscan2
- ZNF804A | c.1666A>G p.R556G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100169355; called by muse, varscan2
- ABCG5 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABHD11 | c.328dup p.H110Pfs*83 | Frame Shift Ins (INS) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- ABL2 | c.1297T>G p.L433V (on ENST00000502732 / NM_007314.4; = p.L418V on NM_005158.5) | Missense Mutation (SNP) | VAF 49/200 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ACIN1 | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); called by muse, varscan2
- ACTRT1 | c.214T>C p.Y72H | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADGRB1 | c.3177dup p.X1059_splice | Splice Site (INS) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.2858A>G p.Y953C (on ENST00000370717 / NM_001366005.1; = p.Y940C on NM_012302.4) | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- AGO2 | c.1552G>C p.V518L | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AHCTF1 | c.6070A>G p.K2024E (on ENST00000366508; = p.K1998E on NM_015446.5) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AK7 | c.885T>G p.N295K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AK7 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- AK9 | c.3016A>G p.M1006V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP12 | c.5174A>C p.K1725T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- AL592490.1 | c.2438C>T p.T813I | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2
- ALDH9A1 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- ANK2 | c.9419A>G p.E3140G | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ANKRD36C | c.87A>T p.K29N | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ANKS1B | c.242A>C p.Y81S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AP1G2 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AP3B1 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGAP6 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 34/292 reads (12%) | called by muse, mutect2, varscan2
- ARID1A | c.6371_6379del p.K2124_S2126del | In Frame Del (DEL) | VAF 51/271 reads (19%) | called by mutect2, varscan2
- ARRDC2 | c.683T>G p.M228R | Missense Mutation (SNP) | VAF 91/372 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- ASXL3 | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); called by muse, mutect2
- ATP6V0B | c.259A>G p.K87E | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ATP8A2 | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- ATP8B4 | c.2557T>G p.Y853D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- BAHCC1 | c.1676dup p.I560Hfs*4 | Frame Shift Ins (INS) | VAF 32/148 reads (22%) | called by mutect2, pindel, varscan2
- BMP10 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BNIP2 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- C11orf95 | c.1276T>C p.Y426H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CA1 | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 15/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1C | c.5306A>G p.N1769S | Missense Mutation (SNP) | VAF 67/391 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CACNB1 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CADPS | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CAMK2A | c.1078G>T p.A360S (on ENST00000348628 / NM_171825.2; = p.A371S on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.079); called by muse, varscan2
- CAMTA2 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CAPN10 | c.447dup p.L151Tfs*129 | Frame Shift Ins (INS) | VAF 28/128 reads (22%) | called by mutect2, pindel
- CAPN14 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAPN9 | c.1937T>G p.L646R | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- CASQ1 | c.1070T>G p.V357G | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CASTOR2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 36/654 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2
- CAVIN1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CAVIN3 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- CCDC127 | c.22_23insA p.P8Hfs*8 | Frame Shift Ins (INS) | VAF 29/88 reads (33%) | called by mutect2, varscan2
- CCDC6 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CCDC80 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CCN1 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- CDH19 | c.1516T>C p.Y506H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); called by muse, varscan2
- CDR1 | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CEP104 | c.2418dup p.D807Rfs*11 | Frame Shift Ins (INS) | VAF 61/283 reads (22%) | called by mutect2, pindel, varscan2
- CEP170 | c.574dup p.R192Kfs*10 | Frame Shift Ins (INS) | VAF 33/203 reads (16%) | called by mutect2, pindel, varscan2
- CEP192 | c.2362dup p.T788Nfs*4 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | called by mutect2, varscan2
- CES3 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CFAP221 | c.1000T>A p.L334M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CHRFAM7A | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- CHRNA1 | c.766C>T p.P256S (on ENST00000261007 / NM_001039523.3; = p.P231S on NM_000079.4) | Missense Mutation (SNP) | VAF 104/422 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CKAP5 | c.2489G>T p.S830I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- CNGA2 | c.1382G>A p.G461D | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL21A1 | c.2135del p.K712Rfs*48 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- CRACDL | c.2340del p.D781Tfs*73 | Frame Shift Del (DEL) | VAF 23/143 reads (16%) | called by mutect2, pindel, varscan2
- CREBZF | c.980T>G p.V327G | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CRYBG2 | c.4727T>C p.L1576P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CTNND2 | c.3083dup p.D1029Gfs*75 | Frame Shift Ins (INS) | VAF 26/142 reads (18%) | called by mutect2, pindel, varscan2
- CYP2A13 | c.538A>G p.N180D | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2
- DAB2 | c.86dup p.K30Efs*4 | Frame Shift Ins (INS) | VAF 64/222 reads (29%) | called by mutect2, varscan2
- DAB2IP | c.2794dup p.R932Pfs*28 (on ENST00000408936; = p.R904Pfs*28 on NM_032552.3) | Frame Shift Ins (INS) | VAF 9/50 reads (18%) | called by mutect2, pindel
- DCAF12L2 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DIAPH1 | c.3378dup p.K1127Qfs*6 | Frame Shift Ins (INS) | VAF 67/332 reads (20%) | called by mutect2, pindel, varscan2
- DIP2C | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DNAH10 | c.9889G>A p.G3297R (on ENST00000409039; = p.G3236R on NM_207437.3) | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH2 | c.11546G>A p.S3849N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- DNAH6 | c.6506C>A p.P2169H | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.12308A>G p.D4103G | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, varscan2
- DNMT1 | c.3892G>A p.V1298M | Missense Mutation (SNP) | VAF 77/506 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DOCK11 | c.1191dup p.I398Yfs*7 | Frame Shift Ins (INS) | VAF 19/89 reads (21%) | called by mutect2, pindel
- DOCK2 | c.3152A>C p.K1051T | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPYD | c.1046C>T p.T349I | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- DSP | c.8293C>T p.Q2765* | Nonsense Mutation (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- DST | c.1119_1120dup p.K374Rfs*8 | Frame Shift Ins (INS) | VAF 14/108 reads (13%) | called by mutect2, varscan2
- DTNA | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP2 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- DYNC2I2 | c.1171dup p.H391Pfs*24 | Frame Shift Ins (INS) | VAF 25/120 reads (21%) | called by mutect2, pindel
- EEF1AKNMT | c.1003A>G p.T335A (on ENST00000361735 / NM_015935.5; = p.T249A on NM_014955.3) | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EFCAB5 | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- EIF3A | c.2085T>G p.I695M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ELN | c.1787T>G p.L596R | Missense Mutation (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- EPOP | c.968dup p.A324Gfs*23 | Frame Shift Ins (INS) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- EPS15 | c.135dup p.S46Ifs*48 | Frame Shift Ins (INS) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- ERN2 | c.1261dup p.T421Nfs*17 | Frame Shift Ins (INS) | VAF 14/150 reads (9%) | called by mutect2, pindel
- EVC2 | c.2062A>G p.R688G | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2
- EVC2 | c.830T>C p.L277P | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- EZH2 | c.1169dup p.E391Rfs*4 (on ENST00000460911 / NM_001203247.2; = p.E396Rfs*4 on NM_004456.5) | Frame Shift Ins (INS) | VAF 49/227 reads (22%) | called by mutect2, pindel, varscan2
- FAM47A | c.1117T>C p.S373P | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FAT2 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- FBRSL1 | c.907_908insA p.P303Hfs*177 | Frame Shift Ins (INS) | VAF 35/194 reads (18%) | called by mutect2, pindel, varscan2
- FBXO31 | c.658-2A>G p.X220_splice | Splice Site (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- FBXO46 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 52/384 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FBXO9 | c.379A>T p.I127L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FBXW7 | c.501del p.M168* | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- FCGR2C | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP15 | c.1994dup p.E666Gfs*37 | Frame Shift Ins (INS) | VAF 36/164 reads (22%) | called by mutect2, varscan2
- FLRT1 | c.366dup p.I123Hfs*38 | Frame Shift Ins (INS) | VAF 23/150 reads (15%) | called by mutect2, pindel, varscan2
- FLT1 | c.3470T>C p.L1157S | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FN1 | c.310A>G p.N104D | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.626); called by muse, varscan2
- FREM3 | c.211dup p.V71Gfs*103 | Frame Shift Ins (INS) | VAF 22/100 reads (22%) | called by mutect2, pindel, varscan2
- FSIP2 | c.10275G>T p.K3425N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FYTTD1 | c.519dup p.T174Yfs*6 | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by mutect2, pindel
- GEN1 | c.273_274del p.Q91Hfs*20 | Frame Shift Del (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- GIMAP4 | c.533T>C p.L178S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GNB1 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 57/278 reads (21%) | called by mutect2, pindel, varscan2
- GRIN2D | c.2002A>T p.I668F | Missense Mutation (SNP) | VAF 92/318 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM1 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, varscan2
- GTF3C1 | c.3034T>C p.Y1012H | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HABP2 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- HHLA1 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HK3 | c.1790T>C p.L597P | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HLA-A | c.1012G>T p.G338C (on ENST00000376806; = p.D338Y on NM_002116.8) | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HMOX2 | c.784A>T p.M262L | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMX3 | c.757A>C p.S253R | Missense Mutation (SNP) | VAF 117/487 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPLL | c.729+2T>C p.X243_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- HOXA3 | c.845C>A p.S282* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- HSPA1L | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA4 | c.2396del p.N799Mfs*50 | Frame Shift Del (DEL) | VAF 34/244 reads (14%) | called by mutect2, pindel, varscan2
- HTR1E | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- IDH3B | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 31/646 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFT140 | c.2768A>G p.Y923C | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- IGLV1-36 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- IL13RA2 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IL24 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ING3 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.959); called by muse, mutect2
- INHA | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- INHBA | c.539dup p.H181Afs*23 | Frame Shift Ins (INS) | VAF 49/227 reads (22%) | called by mutect2, pindel, varscan2
- INTS4 | c.483T>A p.D161E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- IQGAP3 | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNJ11 | c.968A>C p.D323A | Missense Mutation (SNP) | VAF 80/351 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- KCNT1 | c.1713-2A>G p.X571_splice (on ENST00000488444; = p.X590_splice on NM_020822.3) | Splice Site (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2, varscan2
- KIAA0753 | c.2449del p.I817Sfs*4 | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel
- KLHL22 | c.1625T>C p.L542P | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KLHL32 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KMO | c.234A>T p.Q78H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.667); called by muse, varscan2
- KMT2C | c.2506dup p.S836Ffs*4 | Frame Shift Ins (INS) | VAF 8/86 reads (9%) | called by mutect2, pindel
- KRT5 | c.1480G>A p.V494I | Missense Mutation (SNP) | VAF 81/322 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- KRTAP10-12 | c.120dup p.C41Lfs*28 | Frame Shift Ins (INS) | VAF 73/331 reads (22%) | called by mutect2, pindel, varscan2
- LAMP1 | c.7G>C p.A3P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2
- LEPR | c.386T>A p.I129K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- LGR6 | c.2608C>A p.L870M (on ENST00000367278 / NM_001017403.1; = p.L818M on NM_021636.3) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LIN9 | c.1251+2T>C p.X417_splice (on ENST00000366808 / NM_001270410.2; = p.X362_splice on NM_173083.3 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- LMF1 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LMNB2 | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- LPA | c.5521T>G p.F1841V | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAG | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1A | c.4836A>C p.E1612D | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- MAP3K14 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 28/543 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.074); called by muse, mutect2
- MAP3K6 | c.3842C>A p.S1281Y | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2
- MAP3K6 | c.1687-3_1687-2del p.X563_splice | Splice Site (DEL) | VAF 97/502 reads (19%) | called by mutect2, pindel, varscan2
- MED12 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MED13 | c.2139dup p.D714Rfs*2 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | called by mutect2, pindel, varscan2
- MED13L | c.821-2A>G p.X274_splice | Splice Site (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- MEF2D | c.1554+2T>C p.X518_splice | Splice Site (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- MGAT4D | c.751T>C p.Y251H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRC1 | c.2288C>A p.S763Y | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRI1 | c.1027dup p.V343Gfs*5 (on ENST00000040663 / NM_001031727.4; = p.V296Gfs*5 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 29/139 reads (21%) | called by mutect2, pindel, varscan2
- MROH7 | c.2408T>G p.L803R | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MRPL10 | c.161T>C p.I54T | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MSGN1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MTMR11 | c.1994T>G p.L665R (on ENST00000439741 / NM_001145862.2; = p.L593R on NM_181873.3) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5B | c.15982T>C p.C5328R | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- MYBL2 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYBPC2 | c.20-1G>A p.X7_splice | Splice Site (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2, varscan2
- MYO15A | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 57/405 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MYO5B | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 34/744 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.159); called by muse, mutect2
- N4BP2 | c.4330+2T>C p.X1444_splice | Splice Site (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- NBPF12 | c.2249C>T p.A750V | Missense Mutation (SNP) | VAF 88/528 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- NCOA3 | c.3376T>G p.F1126V | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2
- NENF | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- NFATC3 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.042); called by muse, mutect2
- NHLRC1 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 17/373 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- NIPBL | c.6546dup p.H2183Tfs*4 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- NLRP11 | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2
- NOTCH1 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 174/681 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- NPR2 | c.2111dup p.A705Gfs*2 | Frame Shift Ins (INS) | VAF 74/401 reads (18%) | called by mutect2, pindel, varscan2
- NSUN6 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- NT5DC1 | c.109T>G p.F37V | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.622); called by muse, varscan2
- NTF3 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- ODF2 | c.2447T>C p.F816S (on ENST00000434106 / NM_153433.2; = p.F792S on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10S1 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2
- OR4A47 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4N2 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 81/640 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5T3 | c.932dup p.A312Gfs*? | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by pindel, varscan2
- OR8B3 | c.756dup p.G253Wfs*9 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, varscan2
- OSBPL5 | c.979A>G p.S327G | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSR2 | c.7A>G p.S3G | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- P2RX1 | c.58del p.R20Afs*16 | Frame Shift Del (DEL) | VAF 25/227 reads (11%) | called by mutect2, pindel, varscan2
- P2RX3 | c.1022T>C p.I341T | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PAGE1 | c.144T>A p.D48E | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAM | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PANK2 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PARD3 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- PARD3B | c.2564del p.K855Sfs*13 (on ENST00000406610 / NM_001302769.2; = p.K786Sfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 38/177 reads (21%) | called by mutect2, pindel, varscan2
- PCNT | c.7286T>A p.I2429K | Missense Mutation (SNP) | VAF 108/426 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCNX3 | c.4394G>A p.S1465N | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- PDE4DIP | c.1904A>C p.N635T | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- PDE6B | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PDS5A | c.1883T>C p.I628T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- PDZK1 | c.356T>C p.L119P | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGLYRP2 | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 60/447 reads (13%) | called by muse, mutect2, varscan2
- PHACTR4 | c.613A>G p.T205A (on ENST00000373839 / NM_001350159.2; = p.T215A on NM_023923.4) | Missense Mutation (SNP) | VAF 32/238 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHETA1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 91/317 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- PIEZO1 | c.4430T>C p.L1477P | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIGN | c.2267T>C p.V756A | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLOD1 | c.1827G>C p.E609D | Missense Mutation (SNP) | VAF 27/700 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); called by muse, mutect2
- PLPPR3 | c.1825G>A p.G609S (on ENST00000520876 / NM_001270366.2; = p.G637S on NM_024888.2) | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- PLXNA1 | c.2858C>A p.P953H | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PLXNB1 | c.4550A>G p.Q1517R | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- PMEPA1 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PMS2 | c.2175-1G>A p.X725_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- POLQ | c.4004T>C p.M1335T | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- POLR3A | c.1984A>G p.N662D | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- POM121C | c.528dup p.S177Lfs*70 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | called by mutect2, pindel
- PON3 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 25/487 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- PPP1R12A | c.737A>G p.E246G | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R3C | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PPP3R1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP6R2 | c.1640A>G p.E547G | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PRAMEF15 | c.1255dup p.R419Pfs*7 | Frame Shift Ins (INS) | VAF 196/838 reads (23%) | called by mutect2, varscan2
- PRIMA1 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.991); called by muse, varscan2
- PRPF40B | c.26del p.P9Lfs*16 (on ENST00000380281; = p.P3Lfs*16 on NM_012272.3) | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- PRR14L | c.5708_5710del p.L1903del | In Frame Del (DEL) | VAF 22/88 reads (25%) | called by mutect2, pindel, varscan2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 14/72 reads (19%) | called by pindel, varscan2
- PTPRF | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PUSL1 | c.82dup p.V28Gfs*115 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 29/166 reads (17%) | called by mutect2, varscan2
- R3HDM1 | c.2910dup p.A971Sfs*21 | Frame Shift Ins (INS) | VAF 38/184 reads (21%) | called by mutect2, pindel, varscan2
- RAP1GAP2 | c.1301C>A p.T434N | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RASGRP4 | c.1149C>G p.Y383* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- RAX | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 15/397 reads (4%) | called by muse, mutect2
- RBBP5 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); called by muse, mutect2
- RGS3 | c.1829T>C p.L610P (on ENST00000350696 / NM_001282923.2; = p.L498P on NM_017790.4) | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RIC8A | c.1093A>C p.T365P (on ENST00000526104 / NM_001286134.1; = p.T371P on NM_021932.5) | Missense Mutation (SNP) | VAF 74/306 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.876); called by muse, varscan2
- RIC8A | c.1163T>C p.V388A (on ENST00000526104 / NM_001286134.1; = p.V394A on NM_021932.5) | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- RIMS4 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- RNF115 | c.608dup p.A204Sfs*2 | Frame Shift Ins (INS) | VAF 39/186 reads (21%) | called by mutect2, pindel, varscan2
- RPGR | c.662A>G p.K221R | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RRNAD1 | c.1175A>T p.N392I | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RTL9 | c.2821dup p.T941Nfs*59 | Frame Shift Ins (INS) | VAF 68/350 reads (19%) | called by mutect2, pindel, varscan2
- RTN2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- RUFY3 | c.1586del p.N529Mfs*4 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- RXFP1 | c.310T>C p.C104R | Missense Mutation (SNP) | VAF 63/267 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S1PR2 | c.868T>C p.W290R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- SALL1 | c.1756A>G p.S586G | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SAP130 | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCART1 | c.1438dup p.A480Gfs*6 | Frame Shift Ins (INS) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- SCN1A | c.2861A>G p.E954G (on ENST00000303395 / NM_001202435.3; = p.E943G on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/516 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCRIB | c.4669dup p.Q1557Pfs*15 | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- SEC23B | c.1928G>A p.S643N | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SEC24C | c.1076C>A p.T359N | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- SELENOM | c.129+2T>C p.X43_splice | Splice Site (SNP) | VAF 55/232 reads (24%) | called by muse, mutect2, varscan2
- SEMA6C | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1B | c.2888A>G p.K963R | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2
- SETDB2 | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SF3B2 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- SH3BGRL | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHANK2 | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIPA1L2 | c.2206A>G p.K736E | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SKI | c.1095+2T>C p.X365_splice | Splice Site (SNP) | VAF 34/192 reads (18%) | called by muse, mutect2, varscan2
- SLC13A4 | c.1726T>C p.C576R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC17A2 | c.12G>T p.K4N | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC18A3 | c.137A>G p.D46G | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC27A5 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- SLCO4C1 | c.104T>C p.L35S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- SLITRK2 | c.2069dup p.P691Tfs*31 | Frame Shift Ins (INS) | VAF 42/228 reads (18%) | called by pindel, varscan2
- SLITRK5 | c.627dup p.N210Efs*17 | Frame Shift Ins (INS) | VAF 55/263 reads (21%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.2375dup p.P794Tfs*5 | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- SMARCE1 | c.449A>G p.E150G | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SMN1 | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.078); called by muse, varscan2
- SNX3 | c.384-2A>G p.X128_splice | Splice Site (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- SOCS6 | c.177A>C p.E59D | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SOGA1 | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SPIN1 | c.431A>G p.E144G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- SPOCK1 | c.111T>A p.N37K | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STAG2 | c.2264A>C p.K755T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- STK19 | c.652T>C p.Y218H | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SUMF2 | c.548C>A p.P183H (on ENST00000652303; = p.P164H on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SV2B | c.1898T>C p.L633S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SYN2 | c.402dup p.V135Sfs*6 | Frame Shift Ins (INS) | VAF 60/288 reads (21%) | called by mutect2, pindel, varscan2
- SYNGR2 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 79/333 reads (24%) | called by muse, mutect2, varscan2
- SYT2 | c.919+2T>C p.X307_splice | Splice Site (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- TACR3 | c.422T>C p.V141A | Missense Mutation (SNP) | VAF 23/518 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- TBC1D20 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 26/251 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- TBC1D9B | c.3368A>G p.E1123G (on ENST00000356834 / NM_198868.3; = p.E1106G on NM_015043.4) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TECPR2 | c.3586T>C p.S1196P | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TENM4 | c.7357A>G p.K2453E | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TENT5B | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 11/312 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2
- TEP1 | c.4918C>A p.Q1640K | Missense Mutation (SNP) | VAF 56/407 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TESK1 | c.67C>G p.P23A | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- TEX10 | c.382A>C p.K128Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TFEB | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2
- TGM4 | c.1430T>C p.V477A | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- THSD4 | c.2957T>C p.V986A | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TIMP3 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 49/468 reads (10%) | called by muse, mutect2, varscan2
- TJAP1 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TM9SF3 | c.200T>C p.V67A | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM184B | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.356); called by muse, mutect2
- TMEM266 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.964); called by muse, varscan2
- TNR | c.177dup p.E60Rfs*13 | Frame Shift Ins (INS) | VAF 91/397 reads (23%) | called by mutect2, pindel, varscan2
- TOE1 | c.956A>G p.H319R | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOMM40 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPRA1 | c.783T>A p.D261E | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC4 | c.239dup p.N80Kfs*2 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TRPM3 | c.2012T>C p.L671P (on ENST00000357533 / NM_001366142.2; = p.L514P on NM_020952.6) | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRPV5 | c.1880A>G p.D627G | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TSGA10 | c.1658T>C p.L553P | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSSK2 | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.006); called by muse, mutect2
- TSSK3 | c.486C>G p.H162Q | Missense Mutation (SNP) | VAF 76/270 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, varscan2
- TTC31 | c.876G>A p.Q292= | Splice Region (SNP) | VAF 86/272 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.78343dup p.T26115Nfs*5 (on ENST00000591111; = p.T18691Nfs*5 on NM_003319.4) | Frame Shift Ins (INS) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- UBAP2L | c.2764A>G p.S922G | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, varscan2
- UGT2B28 | c.1457T>C p.F486S | Missense Mutation (SNP) | VAF 71/346 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- UPB1 | c.841T>C p.C281R | Missense Mutation (SNP) | VAF 132/536 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- URB1 | c.1951T>G p.L651V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USH2A | c.2178T>G p.C726W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP28 | c.569T>A p.V190D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP43 | c.3262T>C p.S1088P | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAM1 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS51 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- WASHC2C | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDFY4 | c.4805T>C p.V1602A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT7B | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 46/441 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YTHDF3 | c.381dup p.P128Sfs*3 | Frame Shift Ins (INS) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- ZAN | c.3900T>G p.N1300K | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZAR1L | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ZBED1 | c.58dup p.R20Pfs*69 | Frame Shift Ins (INS) | VAF 23/203 reads (11%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2
- ZNF354B | c.1375A>C p.I459L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF383 | c.1022A>C p.K341T | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ZNF407 | c.1472_1473dup p.T492* | Frame Shift Ins (INS) | VAF 78/356 reads (22%) | called by mutect2, varscan2
- ZNF45 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- ZNF492 | c.1290dup p.N431* | Frame Shift Ins (INS) | VAF 8/52 reads (15%) | called by mutect2, varscan2
- ZNF644 | c.1397A>G p.H466R | Missense Mutation (SNP) | VAF 82/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF721 | c.2267T>C p.L756P (on ENST00000338977; = p.L768P on NM_133474.4) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF835 | c.581A>G p.H194R | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF84 | c.1655T>C p.F552S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF862 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF92 | c.1397C>T p.S466L (on ENST00000328747 / NM_152626.4; = p.S397L on NM_007139.4) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ZYG11B | c.2141T>A p.I714N | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ABCA13 | c.8298G>A p.Q2766= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99081663; called by muse, mutect2, varscan2
- ABCB1 | c.426A>G p.R142= | Silent (SNP) | VAF 73/319 reads (23%) | called by muse, mutect2, varscan2
- ABCB4 | c.1296C>T p.G432= | Silent (SNP) | VAF 87/409 reads (21%) | called by muse, mutect2, varscan2
- ABCC1 | c.1899G>A p.R633= | Silent (SNP) | VAF 27/218 reads (12%) | catalogued as COSV60693733; called by muse, mutect2, varscan2
- ABCC6 | c.2661C>T p.R887= | Silent (SNP) | VAF 53/517 reads (10%) | catalogued as rs376958386; called by muse, mutect2, varscan2
- ABHD16B | c.1083G>A p.A361= | Silent (SNP) | VAF 29/198 reads (15%) | called by muse, mutect2, varscan2
- AC136428.1 | c.237C>T p.Y79= | Silent (SNP) | VAF 40/530 reads (8%) | catalogued as rs369050451; called by muse, mutect2
- ADAM28 | c.1194T>C p.A398= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- ADAMTSL4 | c.60G>A p.Q20= | Silent (SNP) | VAF 26/432 reads (6%) | called by muse, mutect2
- ADRA2A | c.1305G>A p.S435= | Silent (SNP) | VAF 90/452 reads (20%) | catalogued as rs770181278, COSV54526721, COSV54529380; called by muse, mutect2, varscan2
- AJM1 | c.2142C>T p.R714= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as rs1208125951, COSV56032178; called by muse, mutect2, varscan2
- AKAP3 | c.432T>C p.N144= | Silent (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- AL592490.1 | c.2439A>G p.T813= | Silent (SNP) | VAF 54/267 reads (20%) | called by muse, varscan2
- ANO3 | c.277A>C p.R93= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- ANPEP | c.1107C>T p.F369= | Silent (SNP) | VAF 75/324 reads (23%) | catalogued as rs367827322; called by muse, mutect2, varscan2
- APBA1 | c.411C>T p.H137= | Silent (SNP) | VAF 27/281 reads (10%) | catalogued as rs758145170; called by muse, mutect2, varscan2
- ARAP3 | c.2115G>A p.P705= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs368167828; called by muse, mutect2, varscan2
- ARFRP1 | c.366G>A p.E122= | Silent (SNP) | VAF 31/166 reads (19%) | called by muse, varscan2
- ARHGAP36 | c.618G>A p.L206= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ARMH1 | c.1173G>A p.A391= | Silent (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- ASB18 | c.975C>T p.G325= | Silent (SNP) | VAF 68/294 reads (23%) | catalogued as rs1205941982; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1272G>A p.A424= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs763356558, COSV52352928; called by muse, mutect2, varscan2
- ATP8B3 | c.3186G>A p.P1062= | Silent (SNP) | VAF 67/225 reads (30%) | catalogued as rs368555564; called by muse, mutect2, varscan2
- ATRNL1 | c.2952T>C p.I984= | Silent (SNP) | VAF 40/157 reads (25%) | called by muse, mutect2, varscan2
- AVPR1B | c.912C>T p.S304= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- B3GALNT2 | c.744A>G p.G248= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as COSV58355984; called by muse, varscan2
- B4GALNT3 | c.1737G>A p.R579= | Silent (SNP) | VAF 27/509 reads (5%) | catalogued as COSV56758273; called by muse, mutect2
- BRCA2 | c.6360A>G p.S2120= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- CACNA1G | c.4881C>A p.T1627= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2
- CCDC80 | c.2691A>G p.Q897= | Silent (SNP) | VAF 78/287 reads (27%) | called by muse, mutect2, varscan2
- CCDC88C | c.4704G>A p.S1568= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs371969147; called by muse, mutect2, varscan2
- CCKBR | c.420G>A p.V140= | Silent (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- CD207 | c.459A>G p.Q153= | Silent (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- CDH23 | c.1617C>A p.G539= | Silent (SNP) | VAF 106/388 reads (27%) | catalogued as COSV99819415; called by muse, mutect2, varscan2
- CEP57L1 | c.438A>G p.E146= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- CHL1 | c.1353T>C p.P451= (on ENST00000397491 / NM_001253387.1; = p.P467= on NM_006614.4) | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV56595136; called by muse, mutect2, varscan2
- CLCN1 | c.2790T>C p.P930= | Silent (SNP) | VAF 32/174 reads (18%) | called by muse, mutect2, varscan2
- CLCN6 | c.510G>A p.K170= | Silent (SNP) | VAF 59/338 reads (17%) | called by muse, mutect2, varscan2
- CNBD1 | c.1005T>C p.I335= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- CNNM1 | c.1306C>T p.L436= | Silent (SNP) | VAF 20/386 reads (5%) | called by muse, mutect2
- COG4 | c.813C>A p.I271= | Silent (SNP) | VAF 40/370 reads (11%) | called by muse, mutect2, varscan2
- COL18A1 | c.4086A>C p.P1362= (on ENST00000359759 / NM_130444.3; = p.P1127= on NM_030582.4) | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs751825604; ClinVar: likely benign; called by muse, varscan2
- COL4A2 | c.5061G>T p.S1687= | Silent (SNP) | VAF 93/376 reads (25%) | catalogued as COSV100847421; called by muse, mutect2, varscan2
- CPA1 | c.315C>T p.F105= | Silent (SNP) | VAF 36/374 reads (10%) | called by muse, mutect2
- CRKL | c.636C>A p.T212= | Silent (SNP) | VAF 47/404 reads (12%) | called by muse, mutect2, varscan2
- CSPP1 | c.3720G>A p.Q1240= (on ENST00000676605; = p.Q1199= on NM_024790.6) | Silent (SNP) | VAF 64/503 reads (13%) | called by muse, mutect2, varscan2
- DNAH2 | c.7494C>A p.P2498= | Silent (SNP) | VAF 13/225 reads (6%) | catalogued as COSV101209558; called by muse, mutect2
- DROSHA | c.96A>G p.P32= | Silent (SNP) | VAF 41/205 reads (20%) | called by muse, mutect2, varscan2
- E2F3 | c.150T>C p.A50= | Silent (SNP) | VAF 118/610 reads (19%) | catalogued as rs571431012; called by mutect2, varscan2
- EFNB1 | c.972C>T p.Y324= | Silent (SNP) | VAF 50/398 reads (13%) | catalogued as rs769979924; called by muse, mutect2, varscan2
- ETV1 | c.936C>T p.F312= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs765227604, COSV54137697; called by muse, mutect2, varscan2
- EVPL | c.708G>A p.T236= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as rs1346835988; called by muse, mutect2, varscan2
- FAM117A | c.1239C>T p.S413= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- FAM184B | c.2433C>T p.N811= | Silent (SNP) | VAF 51/380 reads (13%) | catalogued as rs1259700852; called by muse, mutect2, varscan2
- FANCA | c.1947C>A p.P649= | Silent (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2
- FBRSL1 | c.1068G>A p.P356= | Silent (SNP) | VAF 30/367 reads (8%) | catalogued as rs760667447; called by muse, mutect2
- FCGBP | c.1347C>T p.C449= | Silent (SNP) | VAF 26/100 reads (26%) | catalogued as rs1028461683; called by muse, mutect2
- FCRL1 | c.1041C>A p.P347= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100839823; called by muse, mutect2
- FER1L6 | c.231G>A p.E77= | Silent (SNP) | VAF 9/106 reads (8%) | called by muse, mutect2
- FMO5 | c.1383A>G p.L461= | Silent (SNP) | VAF 70/267 reads (26%) | catalogued as COSV54208557; called by muse, mutect2, varscan2
- FOXK1 | c.84A>C p.A28= | Silent (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2
- FOXN4 | c.1098G>A p.Q366= | Silent (SNP) | VAF 14/327 reads (4%) | catalogued as COSV54494541; called by muse, mutect2
- FRY | c.7518A>G p.G2506= | Silent (SNP) | VAF 52/310 reads (17%) | catalogued as rs746920171; called by muse, mutect2, varscan2
- FTCD | c.1287A>G p.T429= | Silent (SNP) | VAF 109/459 reads (24%) | called by muse, mutect2, varscan2
- GABRG1 | c.1308T>C p.I436= | Silent (SNP) | VAF 49/210 reads (23%) | called by muse, mutect2, varscan2
- GAS6 | c.672C>T p.D224= | Silent (SNP) | VAF 64/259 reads (25%) | catalogued as rs200327303, COSV59851462; called by muse, mutect2, varscan2
- GC | c.174A>G p.E58= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- GHRH | c.204G>A p.E68= | Silent (SNP) | VAF 17/331 reads (5%) | called by muse, mutect2
- GLCCI1 | c.702C>T p.I234= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs1380826845, COSV56204841; called by muse, mutect2
- GLYCTK | c.867T>C p.S289= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- GPR1 | c.57A>G p.L19= | Silent (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- GPR146 | c.189C>T p.D63= | Silent (SNP) | VAF 85/415 reads (20%) | catalogued as rs759455297, COSV52466213, COSV52466432; called by muse, mutect2, varscan2
- GPR173 | c.942C>A p.A314= | Silent (SNP) | VAF 55/318 reads (17%) | called by muse, mutect2, varscan2
- GRINA | c.1044G>A p.A348= | Silent (SNP) | VAF 30/217 reads (14%) | catalogued as rs184930535, COSV57593200; called by muse, mutect2, varscan2
- GTF3C2 | c.546A>G p.R182= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs1318362798; called by muse, mutect2
- GYG2 | c.183A>G p.R61= | Silent (SNP) | VAF 49/256 reads (19%) | called by muse, mutect2, varscan2
- HAUS5 | c.690A>G p.S230= | Silent (SNP) | VAF 22/155 reads (14%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.615T>C p.H205= (on ENST00000394468 / NM_001039372.4; = p.H193= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/269 reads (17%) | called by muse, mutect2, varscan2
- HKDC1 | c.1128C>T p.T376= | Silent (SNP) | VAF 78/352 reads (22%) | catalogued as rs1564732214; called by muse, mutect2, varscan2
- HLA-DQB2 | c.252C>T p.S84= | Silent (SNP) | VAF 36/371 reads (10%) | called by muse, mutect2, varscan2
- HMCN2 | c.12459C>T p.R4153= | Silent (SNP) | VAF 20/484 reads (4%) | catalogued as rs1259493531; called by muse, mutect2
- HOMEZ | c.186T>C p.S62= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as rs1356691459; called by muse, mutect2, varscan2
- HOXC5 | c.468G>A p.K156= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- HSF4 | c.348C>T p.R116= | Silent (SNP) | VAF 22/314 reads (7%) | catalogued as rs757622006, COSV50457475; called by muse, mutect2
- HTR2A | c.711C>T p.I237= | Silent (SNP) | VAF 45/220 reads (20%) | catalogued as rs770236124, COSV66328037; called by muse, mutect2, varscan2
- IDH3B | c.885C>T p.S295= | Silent (SNP) | VAF 39/463 reads (8%) | catalogued as COSV61389738; called by muse, mutect2
- IGSF9 | c.3405T>A p.V1135= (on ENST00000368094 / NM_001135050.2; = p.V1119= on NM_020789.4) | Silent (SNP) | VAF 54/242 reads (22%) | called by muse, mutect2, varscan2
- IQSEC3 | c.1164G>A p.P388= (on ENST00000538872 / NM_001170738.2; = p.P85= on NM_015232.1) | Silent (SNP) | VAF 106/313 reads (34%) | catalogued as rs1555087332; called by muse, mutect2, varscan2
- IRX1 | c.1002A>G p.P334= | Silent (SNP) | VAF 18/86 reads (21%) | called by muse, mutect2, varscan2
- ITGA2B | c.936C>T p.R312= | Silent (SNP) | VAF 85/377 reads (23%) | catalogued as rs775270140; called by muse, mutect2, varscan2
- ITPR3 | c.6252T>C p.G2084= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- JMJD1C | c.1242A>G p.G414= | Silent (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- JPH3 | c.216C>T p.G72= | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as rs372138524; called by muse, mutect2, varscan2
- JSRP1 | c.327G>C p.P109= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as COSV99678300; called by muse, mutect2, varscan2
- KARS1 | c.616C>T p.L206= | Silent (SNP) | VAF 10/211 reads (5%) | catalogued as COSV56694116; called by muse, mutect2
- KATNB1 | c.1068C>T p.S356= | Silent (SNP) | VAF 41/159 reads (26%) | catalogued as rs200545074; called by muse, mutect2, varscan2
- KCND1 | c.744G>A p.L248= | Silent (SNP) | VAF 35/275 reads (13%) | catalogued as rs1569518670; called by muse, mutect2, varscan2
- KCTD21 | c.465C>T p.F155= | Silent (SNP) | VAF 135/480 reads (28%) | catalogued as rs1565381293; called by muse, mutect2, varscan2
- KDM6B | c.96G>A p.P32= | Silent (SNP) | VAF 55/420 reads (13%) | catalogued as rs757574367, COSV54684309; called by muse, varscan2
- KERA | c.642T>C p.N214= | Silent (SNP) | VAF 44/155 reads (28%) | called by muse, mutect2, varscan2
- KHDRBS3 | c.117C>A p.G39= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- KHNYN | c.1128C>T p.C376= | Silent (SNP) | VAF 32/146 reads (22%) | catalogued as rs146188248; called by muse, mutect2, varscan2
- KIAA1549 | c.3567A>G p.Q1189= | Silent (SNP) | VAF 72/254 reads (28%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1263C>T p.Y421= (on ENST00000395676; = p.Y1062= on NM_138433.5) | Silent (SNP) | VAF 62/214 reads (29%) | catalogued as rs930545178, COSV67464998; called by muse, mutect2, varscan2
240 further variants in this file (0 protein-altering or splice-affecting, 117 silent, 123 other) are not listed here.
